CCDI case PBCKVN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a585ab04-b116-4920-a086-eaa179a65049

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,443 days).

Biospecimens (2 samples)
- Sample 0DU9ML: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9MZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
